Gene-level copy-number profile of tumor specimen TCGA-CD-8533-01A from TCGA case TCGA-CD-8533, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.8 years (17,821 days).
Specimen TCGA-CD-8533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.174a9a78-9f46-47fc-8265-802c20c6808f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8533-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dbfbcb68-c0af-46c9-8d91-18baf7e2752d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,328; copy number 2: 21,088; copy number 3: 22,403; copy number 4: 9,300; copy number 5: 855; copy number 6: 962; copy number 7: 1,492; copy number 8: 442; copy number 9: 211; copy number 10: 104; copy number 11: 291; copy number 12: 1; copy number 13: 12; copy number 14: 38; copy number 15: 107; copy number 18: 83; copy number 19: 45; copy number 22: 34; copy number 43: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8533-01A-11D-2338-01): tumor purity 0.79, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,599,436, 9 genes (within-gene range 0–10): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,865 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:207,166,120–208,854,503, 45 genes, copy number 8–15: MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1, PTH2R, ARPC1BP1, H3P9, AC019185.1, AC019185.2.
- chr4:30,718,805–33,437,877, 16 genes, copy number 7: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1.
- chr5:58,969,038–60,522,120, 1 gene, copy number 7 (within-gene range 4–7): PDE4D.
- chr5:59,528,861–67,806,600, 98 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr6:141,019,788–144,853,034, 52 genes, copy number 10–22 (within-gene range 6–22): AL357080.1, AL355596.2, AL355596.1, RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1.
- chr7:6,952,625–53,947,804, 747 genes, copy number 7 (broad region; genes not listed).
- chr11:9,311,284–10,294,219, 20 genes, copy number 14 (within-gene range 3–14): PRR13P2, IPO7, SNORA23, AC132192.1, AC132192.2, ZNF143, WEE1, AC122179.1, RPL23AP65, AC011979.2, AC011979.1, SWAP70, RN7SKP50, LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3.
- chr11:28,144,907–28,287,625, 3 genes, copy number 18: ATP5MGP8, RN7SKP158, AC104978.1.
- chr11:69,294,151–71,252,577, 46 genes, copy number 18: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:79,402,022–82,718,299, 18 genes, copy number 14 (within-gene range 3–20): MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr11:94,305,592–94,307,721, 1 gene, copy number 18: IZUMO1R.
- chr11:129,202,966–129,203,070, 1 gene, copy number 12: RNU6-874P.
- chr13:31,739,526–48,134,534, 275 genes, copy number 8 (broad region; genes not listed).
- chr13:48,531,800–54,687,547, 126 genes, copy number 10–43 (broad region; genes not listed).
- chr13:57,991,350–74,565,445, 139 genes, copy number 10–19 (broad region; genes not listed).
- chr13:85,837,126–99,590,508, 172 genes, copy number 11 (broad region; genes not listed).
- chr13:99,643,059–99,690,971, 2 genes, copy number 11: MIR4306, CLYBL-AS2.
- chr19:6,729,914–11,505,839, 253 genes, copy number 8–9 (broad region; genes not listed).
- chr20:8,019,180–47,873,273, 850 genes, copy number 7–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,328. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
